MMRF case MMRF_1957 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/dc46b442-f86c-440f-b0e2-dd7086d05f2c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.4 years (27,522 days); ISS stage: II; Days to last known disease status: 981 days (2.7 years); Days to last follow up: 981 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 144 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 194 days; Days to treatment end: 194 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 196 days; Days to treatment end: 196 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 308 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 0): M Protein 2.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 3.36 g/L; Immunoglobulin A 37.5 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.46 µg/mL; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.83 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 8.6 g/dL; Glucose 5.61 mmol/L; C-Reactive Protein 0.054 mg/dL.
- Day 83 (ECOG 0): M Protein 0.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 3.64 g/L; Immunoglobulin A 11.5 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1.84 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 4.4 mmol/L.
- Day 111 (ECOG 0): M Protein 0.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 4.3 g/L; Immunoglobulin A 10.3 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.08 µg/mL; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 0.91 ×10⁹/L; Platelets 70 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.
- Day 223 (ECOG 0): M Protein 0.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 5.78 g/L; Immunoglobulin A 8.87 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.18 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.45 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 7.7 mmol/L.
- Day 357 (ECOG 0): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 5.18 g/L; Immunoglobulin A 4.35 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.96 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.28 mmol/L.
- Day 439 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 5.65 g/L; Immunoglobulin A 5.27 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.85 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 5.61 mmol/L.
- Day 526: M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 6.22 g/L; Immunoglobulin A 6.99 g/L; Immunoglobulin M 0.78 g/L; Beta 2 Microglobulin 1.46 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.03 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 132 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 7.6 g/dL; Glucose 3.85 mmol/L.
- Day 554: M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 5.72 g/L; Immunoglobulin A 6.08 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.98 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.26 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 5.39 mmol/L.
- Day 645 (ECOG 1): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 4.76 g/L; Immunoglobulin A 7.48 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.68 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.27 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.1 mmol/L; Albumin 34 g/L; Total Protein 6.8 g/dL; Glucose 4.73 mmol/L.
- Day 803: M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 4.53 g/L; Immunoglobulin A 10.3 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 6.87 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.78 ×10⁹/L; Platelets 82 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 5.12 mmol/L.
- Day 897 (ECOG 1): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 4.68 g/L; Immunoglobulin A 11.7 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.08 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.93 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.29 mmol/L.
- Day 981 (ECOG 1): M Protein 0.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 4.07 g/L; Immunoglobulin A 17.2 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.23 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day -14: Weight: 75 kg; Height: 175 cm.

Biospecimens (2 samples)
- Sample MMRF_1957_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_1957_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
